Somatic mutation profile of tumor specimen TCGA-R8-A6MK-01A (aliquot TCGA-R8-A6MK-01A-11D-A32B-08) from TCGA case TCGA-R8-A6MK, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 40.3 years (14,716 days).
Specimen TCGA-R8-A6MK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8dcb12f-8d50-448a-91f0-ac4fbca66c4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R8-A6MK-10A (Blood Derived Normal), aliquot TCGA-R8-A6MK-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/808fbac2-8533-4d52-98e0-d8dbf872fbbb

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 5, In Frame Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARAP2 | c.3901G>A p.E1301K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100394861; called by muse, mutect2, varscan2
- CCS | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 4/92 reads (4%) | catalogued as COSV100040048, COSV59578226; called by muse, mutect2
- CIC | c.4550_4552del p.K1517del | In Frame Del (DEL) | VAF 16/26 reads (62%) | catalogued as rs751580245; called by pindel, varscan2
- DSP | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs749051278, COSV65792211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA1 | c.1133A>G p.D378G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100379679; called by muse, mutect2, varscan2
- FBLN2 | c.2608G>A p.G870S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs111284875, CM1211793, COSV99852412; called by muse, mutect2, varscan2
- HTT | c.6760G>A p.V2254M | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.448); catalogued as COSV61872465; called by muse, mutect2, varscan2
- IFT140 | c.3742A>G p.I1248V | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1412979608, COSV100794385; called by muse, mutect2, varscan2
- KRT6A | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100417048; called by muse, mutect2, varscan2
- PRSS16 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149942995; called by muse, mutect2, varscan2
- PTPRZ1 | c.5344T>C p.Y1782H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051747413, COSV101100340; called by muse, mutect2, varscan2
- RAD50 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750480943, COSV99529150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANBP2 | c.6518T>C p.M2173T | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV99312495; called by muse, mutect2, varscan2
- SLC7A4 | c.430_431del p.M144Vfs*10 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs751355224; called by mutect2, pindel, varscan2
- TENM3 | c.71C>A p.T24K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV69323201; called by muse, mutect2, varscan2
- CIC | c.1110_1113del p.S370Rfs*6 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- LRP1 | c.8339_8341del p.S2780del | In Frame Del (DEL) | VAF 49/166 reads (30%) | called by mutect2, pindel, varscan2
- LRRC73 | c.825_826del p.G276Afs*37 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by pindel, varscan2
- PPL | c.3099_3101del p.L1034del | In Frame Del (DEL) | VAF 22/72 reads (31%) | called by pindel, varscan2
- RBBP6 | c.4323_4324del p.L1443Vfs*8 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- ZNF135 | c.717_720del p.E239Dfs*9 (on ENST00000313434 / NM_001289401.2; = p.E251Dfs*9 on NM_003436.4) | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- AGXT2 | c.420C>T p.V140= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV51488223, COSV99183779; called by muse, mutect2, varscan2
- ATP2A1 | c.1632G>A p.K544= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100837316; called by muse, mutect2
- INPP4B | c.1209A>T p.S403= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV99525216; called by muse, mutect2, varscan2
- MC2R | c.774C>T p.F258= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV100563065; called by muse, mutect2, varscan2
- PLG | c.1230G>A p.Q410= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as COSV99804827; called by muse, mutect2
- SPTA1 | c.5784T>C p.Y1928= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as COSV63756801; called by muse, mutect2, varscan2
- TBR1 | c.1083C>T p.F361= | Silent (SNP) | VAF 51/133 reads (38%) | catalogued as COSV101271489; called by muse, mutect2, varscan2
